CTSP case CTSP-AD1S — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/297b1cb6-df7d-4e75-a17c-592179be7b71

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1949; Vital status: Alive.

Diagnoses (2)
1. Diffuse large B-cell lymphoma, NOS (the primary disease): ICD-O-3 morphology code: 9680/3; Age at diagnosis: 61.4 years (22,410 days); Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage IV; Days to last follow up: 2,028 days (5.6 years); Best overall response: Complete Response Unconfirmed; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High Risk.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Rituximab + Vincristine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: DA-EPOCH-R; Days to treatment start: 29 days; Days to treatment end: 194 days; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Treatment dose max: 7.
   Treatment given: Drug category: Growth factor.
   Treatment given: Therapeutic agents: Filgrastim.
   Treatment given: Therapeutic agents: Methotrexate.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; treatment (type not reported) (Pegfilgrastim); adjuvant Radiation Therapy, NOS, for residual disease.
2. Tumor, NOS: Tissue or organ of origin: Breast, NOS; Age at diagnosis: 63.7 years (23,253 days); Days to diagnosis: 843 days (2.3 years).

Follow-up (17 entries)
- Days to follow up: 0 days; ECOG performance status: 2.
- Days to follow up: 2,028 days (5.6 years); Disease response: Complete Response; Progression or recurrence: No; Days progression-free: 2,027 days (5.5 years); Adverse event: Febrile Neutropenia; Adverse event grade: Grade 3.
- Days to follow up: 2,028 days (5.6 years); Adverse event: Anemia; Adverse event grade: Grade 2.
- Days to follow up: 2,028 days (5.6 years); Adverse event: Hypoalbuminemia; Adverse event grade: Grade 3.
- Days to follow up: 2,028 days (5.6 years); Adverse event: Lymphocyte Count Decreased; Adverse event grade: Grade 4.
- Days to follow up: 2,028 days (5.6 years); Adverse event: Peripheral Sensory Neuropathy; Adverse event grade: Grade 2.
- Days to follow up: 2,028 days (5.6 years); Adverse event: Mucositis Oral; Adverse event grade: Grade 2.
- Days to follow up: 2,028 days (5.6 years); Adverse event: White Blood Cell Decreased; Adverse event grade: Grade 4.
- Days to follow up: 2,028 days (5.6 years); Adverse event: Platelet Count Decreased; Adverse event grade: Grade 3.
- Days to follow up: 2,028 days (5.6 years); Adverse event: Platelet Count Decreased; Adverse event grade: Grade 1.
- Days to follow up: 2,028 days (5.6 years); Adverse event: Platelet Count Decreased; Adverse event grade: Grade 4.
- Days to follow up: 2,028 days (5.6 years); Adverse event: Peripheral Sensory Neuropathy; Adverse event grade: Grade 3.
- Days to follow up: 2,028 days (5.6 years); Adverse event: Hypokalemia; Adverse event grade: Grade 3.
- Days to follow up: 2,028 days (5.6 years); Adverse event: Neutrophil Count Decreased; Adverse event grade: Grade 4.
- Days to follow up: 2,028 days (5.6 years); Adverse event: Anemia; Adverse event grade: Grade 3.
- Days to follow up: 2,028 days (5.6 years); Adverse event: Constipation; Adverse event grade: Grade 2.
- Days to follow up: 2,028 days (5.6 years); Adverse event: Peripheral Sensory Neuropathy; Adverse event grade: Grade 1.

Molecular and laboratory tests
- Lactate Dehydrogenase 656 [Blood test normal range upper: 190].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 132 kg; Height: 170 cm; BMI: 45.7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CTSP-AD1S-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample CTSP-AD1S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide CTSP-AD1S-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 70; Percent normal cells: 40; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 70; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 0.
- Sample DLBCL11350-sample: Sample type: Tumor; Tissue type: Tumor.
